Somatic mutation profile of tumor specimen 0DI3NE from CCDI case PBBVAA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 15.0 years (5,482 days).
Specimen 0DI3NE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b84d1f9e-58ba-48db-a55b-7618851323a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI3JB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f8b3528-93d4-42d6-b1fb-24c74eee3d76

The open-access MAF lists 80 somatic variants for this specimen: 44 protein-altering or splice-affecting, 23 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 23, Intron 7, In Frame Del 3, 5'UTR 2, 5'Flank 2, 3'UTR 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133_135del p.S45del | In Frame Del (DEL) | VAF 236/474 reads (50%) | hotspot (GDC flag); catalogued as rs587776850; ClinVar: pathogenic / other; called by mutect2, pindel, varscan2
- TP53 | c.373A>G p.T125A | Missense Mutation (SNP) | VAF 165/280 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as CM156966, COSV52780750, COSV52951418, COSV53606217; called by muse, mutect2, varscan2
- ASPM | c.8191G>C p.E2731Q | Missense Mutation (SNP) | VAF 245/773 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.074); catalogued as COSV54136038; called by muse, mutect2, varscan2
- ATP6V0A1 | c.1483C>T p.R495W | Missense Mutation (SNP) | VAF 95/164 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); catalogued as rs781278654; called by muse, mutect2, varscan2
- BRAT1 | c.2169_2171del p.L724del | In Frame Del (DEL) | VAF 159/530 reads (30%) | catalogued as rs762488461; called by mutect2, pindel, varscan2
- FSIP1 | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 114/318 reads (36%) | catalogued as COSV100618100; called by mutect2, varscan2
- H2BC15 | c.205G>C p.D69H | Missense Mutation (SNP) | VAF 190/533 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.106); catalogued as COSV57585861; called by muse, mutect2, varscan2
- KMT2C | c.8422G>A p.D2808N | Missense Mutation (SNP) | VAF 261/825 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV100073988; called by muse, mutect2, varscan2
- MAP4K2 | c.2146C>G p.L716V | Missense Mutation (SNP) | VAF 44/674 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs758137477, COSV53641914, COSV53649089; called by muse, mutect2
- MARK1 | c.1831C>G p.R611G | Missense Mutation (SNP) | VAF 175/497 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV100857056; called by muse, mutect2, varscan2
- MSL2 | c.379_381del p.S127del | In Frame Del (DEL) | VAF 268/828 reads (32%) | catalogued as rs776108533; called by pindel, varscan2
- MUC5AC | c.14192G>T p.C4731F | Missense Mutation (SNP) | VAF 273/760 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760658265; called by muse, mutect2, varscan2
- NKIRAS2 | c.380A>T p.Q127L | Missense Mutation (SNP) | VAF 143/549 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as rs1555653563; called by muse, mutect2, varscan2
- PRKD2 | c.548G>C p.S183T | Missense Mutation (SNP) | VAF 51/503 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV52186772; called by muse, mutect2, varscan2
- RANBP1 | c.183G>C p.E61D | Missense Mutation (SNP) | VAF 325/921 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as rs756998095; called by muse, mutect2, varscan2
- SMTN | c.2726A>T p.E909V | Missense Mutation (SNP) | VAF 330/958 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60781653; called by muse, varscan2
- STARD9 | c.7637C>G p.S2546C | Missense Mutation (SNP) | VAF 258/669 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.423); catalogued as rs1349147467; called by muse, mutect2, varscan2
- THEM5 | c.619G>C p.D207H | Missense Mutation (SNP) | VAF 298/906 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV64313331; called by muse, mutect2
- VWA5B1 | c.1088T>A p.I363N | Missense Mutation (SNP) | VAF 72/1147 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99233585; called by muse, mutect2
- BMF | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 23/593 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.48); called by muse, mutect2
- CHD8 | c.1276G>A p.E426K (on ENST00000646647 / NM_001170629.2; = p.E147K on NM_020920.4) | Missense Mutation (SNP) | VAF 22/850 reads (3%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.145); called by muse, mutect2
- CTSA | c.1006G>C p.A336P | Missense Mutation (SNP) | VAF 56/883 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.29); called by muse, mutect2
- CTSG | c.413C>A p.P138H | Missense Mutation (SNP) | VAF 206/687 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EDA2R | c.499A>C p.N167H | Missense Mutation (SNP) | VAF 228/742 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ELP4 | c.701A>T p.N234I (on ENST00000350638; = p.N233I on NM_019040.5) | Missense Mutation (SNP) | VAF 75/265 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- FADS2 | c.327C>G p.I109M | Missense Mutation (SNP) | VAF 23/616 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.017); called by muse, mutect2
- GRXCR1 | c.344C>G p.A115G | Missense Mutation (SNP) | VAF 172/960 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); called by muse, varscan2
- GTPBP6 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 619/1547 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, varscan2
- HACE1 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 92/386 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HEXA | c.11C>G p.S4C | Missense Mutation (SNP) | VAF 113/341 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KLHL11 | c.647C>T p.T216I | Missense Mutation (SNP) | VAF 25/519 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.257); called by muse, mutect2
- MDC1 | c.5317C>T p.P1773S | Missense Mutation (SNP) | VAF 44/787 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); called by muse, mutect2
- MID2 | c.2029C>T p.H677Y | Missense Mutation (SNP) | VAF 34/970 reads (4%) | SIFT tolerated (0.64); PolyPhen benign (0.013); called by muse, mutect2
- NCAM1 | c.400G>C p.D134H | Missense Mutation (SNP) | VAF 173/701 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- OR10W1 | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 220/587 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PHAX | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 249/672 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by mutect2, varscan2
- PPP2R5E | c.1328G>T p.R443L | Missense Mutation (SNP) | VAF 143/387 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PTPRJ | c.175A>T p.T59S | Missense Mutation (SNP) | VAF 180/598 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- REPS2 | c.673+2del p.X225_splice | Splice Site (DEL) | VAF 70/550 reads (13%) | called by mutect2, pindel, varscan2
- TM7SF2 | c.956C>G p.S319C | Missense Mutation (SNP) | VAF 222/696 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.957); called by muse, mutect2
- TMEM132C | c.608G>T p.S203I | Missense Mutation (SNP) | VAF 250/814 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- TRIM22 | c.534C>G p.I178M | Missense Mutation (SNP) | VAF 82/322 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- USP34 | c.8003T>C p.V2668A | Missense Mutation (SNP) | VAF 182/570 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ZNF410 | c.576C>G p.S192R | Missense Mutation (SNP) | VAF 117/451 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- C14orf93 | c.861C>T p.C287= | Silent (SNP) | VAF 28/535 reads (5%) | called by muse, mutect2
- CBWD2 | c.987G>A p.V329= | Silent (SNP) | VAF 170/808 reads (21%) | called by muse, varscan2
- CDH18 | c.1020G>A p.K340= | Silent (SNP) | VAF 169/502 reads (34%) | catalogued as COSV56904772, COSV56951515; called by muse, mutect2, varscan2
- CELF5 | c.903A>T p.S301= | Silent (SNP) | VAF 152/1116 reads (14%) | called by muse, mutect2, varscan2
- COL4A1 | c.1941C>T p.P647= | Silent (SNP) | VAF 48/1032 reads (5%) | called by muse, mutect2
- COL6A2 | c.1218T>G p.G406= | Silent (SNP) | VAF 32/818 reads (4%) | called by muse, mutect2
- DAGLA | c.2013C>A p.T671= | Silent (SNP) | VAF 250/734 reads (34%) | called by muse, mutect2, varscan2
- DSC3 | c.15G>T p.G5= | Silent (SNP) | VAF 156/728 reads (21%) | called by muse, mutect2, varscan2
- FAM117A | c.834C>T p.P278= | Silent (SNP) | VAF 37/600 reads (6%) | catalogued as rs747982886, COSV99544525; called by muse, mutect2
- HIPK4 | c.462C>G p.V154= | Silent (SNP) | VAF 24/523 reads (5%) | catalogued as COSV99397026; called by muse, mutect2
- KIAA1958 | c.2067C>G p.V689= | Silent (SNP) | VAF 183/809 reads (23%) | called by muse, mutect2, varscan2
- KIRREL1 | c.2205A>T p.R735= | Silent (SNP) | VAF 336/992 reads (34%) | called by muse, varscan2
- LGI1 | c.1200T>A p.I400= | Silent (SNP) | VAF 347/889 reads (39%) | called by muse, mutect2, varscan2
- NXT1 | c.363C>G p.P121= | Silent (SNP) | VAF 48/768 reads (6%) | called by muse, mutect2
- PLEKHG4 | c.942G>C p.G314= | Silent (SNP) | VAF 32/1250 reads (3%) | called by muse, mutect2
- RASGRP4 | c.1884C>A p.S628= | Silent (SNP) | VAF 140/466 reads (30%) | catalogued as rs749778728; called by muse, mutect2, varscan2
- RASSF9 | c.819G>T p.L273= | Silent (SNP) | VAF 230/1117 reads (21%) | catalogued as COSV63433403; called by muse, mutect2, varscan2
- SPATA13 | c.108C>A p.T36= | Silent (SNP) | VAF 390/580 reads (67%) | called by mutect2, varscan2
- TDP2 | c.66G>C p.V22= | Silent (SNP) | VAF 39/1051 reads (4%) | called by muse, mutect2
- TMPRSS7 | c.525C>G p.V175= (on ENST00000452346; = p.V62= on NM_001042575.2) | Silent (SNP) | VAF 236/724 reads (33%) | called by muse, varscan2
- TPR | c.177G>A p.K59= | Silent (SNP) | VAF 237/639 reads (37%) | called by muse, mutect2, varscan2
- ZFHX3 | c.4260T>C p.S1420= | Silent (SNP) | VAF 228/1151 reads (20%) | called by muse, mutect2, varscan2
- ZNF676 | c.702T>C p.C234= (on ENST00000650058; = p.C202= on NM_001001411.3) | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV68094114; called by muse, varscan2
- BZW1 | c.-11+447A>G | Intron (SNP) | VAF 158/534 reads (30%) | called by muse, mutect2, varscan2
- GDF5 | c.632-22G>C | Intron (SNP) | VAF 37/472 reads (8%) | called by muse, mutect2
- GNAS | c.970+77C>T | Intron (SNP) | VAF 4/96 reads (4%) | called by muse, mutect2
- H2BC18 | c.-27G>C | 5'UTR (SNP) | VAF 41/361 reads (11%) | called by muse, mutect2, varscan2
- KRTAP4-12 | c.-43C>G | 5'UTR (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- LPCAT2 | c.704-30A>G | Intron (SNP) | VAF 97/345 reads (28%) | catalogued as COSV50899408; called by muse, mutect2, varscan2
- MPP1 | c.102+5499C>A | Intron (SNP) | VAF 33/689 reads (5%) | called by muse, mutect2
- PPP1CC | c.*848A>T | 3'UTR (SNP) | VAF 22/444 reads (5%) | called by muse, mutect2
- PPP2R2C | c.71-585T>C | Intron (SNP) | VAF 57/134 reads (43%) | called by mutect2, varscan2
- SLC26A5 | c.*72G>T | 3'UTR (SNP) | VAF 77/183 reads (42%) | called by muse, mutect2, varscan2
- SREK1 | chr5:66144421 C>T | 5'Flank (SNP) | VAF 346/999 reads (35%) | catalogued as rs1561488302, COSV100485644; called by muse, mutect2, varscan2
- USP54 | c.1144+34C>G | Intron (SNP) | VAF 58/567 reads (10%) | called by muse, mutect2
- WDR38 | chr9:124853444 del AC | 5'Flank (DEL) | VAF 22/148 reads (15%) | catalogued as rs1013550873; called by pindel, varscan2
